Somatic mutation profile of tumor specimen TCGA-VR-A8EP-01A (aliquot TCGA-VR-A8EP-01A-31D-A403-09) from TCGA case TCGA-VR-A8EP, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 51.9 years (18,942 days).
Specimen TCGA-VR-A8EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 686be8fd-a7df-4094-b978-ff4c57316a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EP-10B (Blood Derived Normal), aliquot TCGA-VR-A8EP-10B-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf0ec9a9-6bae-49cc-b65f-fc44efb50e7a

The open-access MAF lists 105 somatic variants for this specimen: 81 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 20, Frame Shift Del 5, Intron 3, Splice Site 2, Nonsense Mutation 2, 3'Flank 1, In Frame Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.3715+2T>C p.X1239_splice | Splice Site (SNP) | VAF 3/34 reads (9%) | catalogued as rs1481842597; called by muse, mutect2
- ALDH4A1 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1457552315, COSV99312197; called by muse, mutect2
- ANGPT1 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 30/119 reads (25%) | catalogued as COSV52430151; called by muse, mutect2, varscan2
- APAF1 | c.614G>A p.R205Q (on ENST00000551964 / NM_181861.2; = p.R194Q on NM_001160.3) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309940307, COSV59663007; called by muse, mutect2, varscan2
- ARHGEF26 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774329182, COSV100726400; called by muse, mutect2, varscan2
- CCDC163 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs759753197, COSV101284472, COSV101284486; called by muse, mutect2
- CNKSR2 | c.2995G>C p.D999H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV101069865; called by muse, mutect2, varscan2
- DPP6 | c.2258C>T p.S753F (on ENST00000377770 / NM_001364500.2; = p.S691F on NM_001936.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59597680; called by muse, mutect2, varscan2
- GIN1 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.14); catalogued as rs1344921909; called by muse, mutect2, varscan2
- LRP1B | c.6241G>A p.G2081R | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); catalogued as rs1276107433; called by muse, mutect2
- MATN2 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.826); catalogued as rs773931953, COSV99645659; called by muse, varscan2
- MUC5B | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as rs1350678704; called by muse, mutect2, varscan2
- NAA25 | c.2509C>G p.L837V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55704279; called by muse, mutect2, varscan2
- NBN | c.572C>A p.P191Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55375508; called by muse, mutect2
- OPA1 | c.2629G>C p.E877Q (on ENST00000361510 / NM_130837.3; = p.E822Q on NM_015560.3) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.109); catalogued as COSV62484036; called by muse, mutect2, varscan2
- OR5D13 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100686839; called by muse, mutect2, varscan2
- PIGN | c.1994A>T p.Y665F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as COSV62950077; called by muse, mutect2, varscan2
- PLA2G5 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1424231041; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs146650273; called by pindel, varscan2
- RB1 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as CM961227, COSV57295856, COSV57306166, COSV57308688; called by muse, mutect2, varscan2
- SPRY4 | c.706T>C p.S236P (on ENST00000434127 / NM_001127496.3; = p.S259P on NM_030964.4) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.8); catalogued as rs1367100203; called by muse, mutect2, varscan2
- TLL1 | c.1960T>C p.Y654H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs1186525006; called by muse, mutect2, varscan2
- TRIM49 | c.215_217del p.K72del | In Frame Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs1178367098; called by pindel, varscan2
- VSTM2A | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs202226834; called by muse, mutect2, varscan2
- ZNF518A | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs782205904; called by muse, mutect2, varscan2
- ZNF793 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV71324972; called by muse, mutect2, varscan2
- AHNAK2 | c.1465T>G p.L489V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BOD1 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFC | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BUB1B | c.2855A>T p.D952V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CACHD1 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CARMIL2 | c.3786C>G p.I1262M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CCDC178 | c.1993del p.Y665Mfs*4 (on ENST00000383096 / NM_001105528.3; = p.Y627Mfs*4 on NM_198995.3) | Frame Shift Del (DEL) | VAF 46/141 reads (33%) | called by mutect2, pindel, varscan2
- CCDC22 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- CDAN1 | c.1745A>G p.Q582R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CEP350 | c.6089G>T p.S2030I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2
- CFAP97 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- COL11A1 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYBG3 | c.7862_7863insTTT p.Q2621delinsHL | In Frame Ins (INS) | VAF 32/83 reads (39%) | called by mutect2, pindel, varscan2
- CSE1L | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- DNAH8 | c.10288T>C p.S3430P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2
- FKBP5 | c.297A>T p.K99N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GAS7 | c.1229G>T p.R410L (on ENST00000432992 / NM_201433.2; = p.R270L on NM_003644.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- GDPGP1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GHR | c.1547T>C p.M516T | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GOLGA5 | c.1747A>T p.S583C | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR132 | c.250del p.L84Wfs*27 | Frame Shift Del (DEL) | VAF 20/30 reads (67%) | called by mutect2, varscan2
- GPR161 | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- HPF1 | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IFI16 | c.2292G>T p.R764S (on ENST00000295809 / NM_001364867.2; = p.R708S on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- IGSF9 | c.2231G>T p.C744F (on ENST00000368094 / NM_001135050.2; = p.C728F on NM_020789.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IQCG | c.365del p.L122* | Frame Shift Del (DEL) | VAF 24/123 reads (20%) | called by mutect2, pindel, varscan2
- ITIH5 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYST | c.10512C>G p.I3504M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- MRPS26 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- MYO6 | c.936T>G p.D312E | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NAV3 | c.3463C>G p.H1155D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPHP3 | c.14C>G p.S5W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGFOD1 | c.1424A>G p.Y475C | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- PKD1L1 | c.7684G>C p.E2562Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PLPP3 | c.929T>C p.M310T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PMPCB | c.102A>T p.S34= | Splice Region (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- RARS2 | c.1537T>G p.S513A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF111 | c.1503T>G p.H501Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ROPN1L | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMD3 | c.822+1G>C p.X274_splice | Splice Site (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- SCN8A | c.5098C>G p.Q1700E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- SCYL1 | c.1163A>T p.Q388L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TAF15 | c.1433G>T p.G478V (on ENST00000605844 / NM_139215.3; = p.G475V on NM_003487.4) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TFAP2B | c.762G>C p.Q254H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM200A | c.1451G>T p.R484M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TSPYL2 | c.1342C>G p.H448D | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- UNC13C | c.5679G>T p.M1893I | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- URGCP | c.871G>A p.D291N (on ENST00000453200 / NM_001077663.3; = p.D282N on NM_017920.4) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- XPO6 | c.799A>C p.T267P | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- YES1 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF439 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF461 | c.740_741del p.E247Vfs*2 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | called by mutect2, pindel, varscan2
- ZNF521 | c.3028C>A p.H1010N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF540 | c.1251G>C p.E417D | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAM18 | c.144C>T p.I48= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- CYLD | c.654T>C p.G218= | Silent (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.723A>G p.V241= | Silent (SNP) | VAF 33/55 reads (60%) | called by muse, mutect2, varscan2
- EHBP1 | c.2184C>T p.I728= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs143884885; called by muse, mutect2, varscan2
- FAIM | c.9T>C p.D3= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- FBN1 | c.6108C>T p.F2036= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- FRMD4B | c.2805G>C p.L935= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- GLB1L2 | c.1182G>A p.L394= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs773473553; called by muse, mutect2, varscan2
- GRIN2D | c.1932G>A p.S644= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs752875753; called by muse, mutect2, varscan2
- HELB | c.849T>G p.L283= | Silent (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- HMGB4 | c.189G>C p.L63= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- ICA1 | c.360C>G p.L120= | Silent (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1867T>C p.L623= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- MOGAT3 | c.132C>G p.V44= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs200949443; called by muse, varscan2
- MYT1L | c.2286C>T p.D762= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- PARPBP | c.645G>A p.E215= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV104404486; called by muse, mutect2, varscan2
- SLC38A10 | c.2376T>C p.P792= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs929254776; called by muse, mutect2, varscan2
- SOX7 | c.333C>T p.N111= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- TENT5B | c.588C>T p.S196= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs143879440; called by muse, mutect2, varscan2
- USP40 | c.2734C>T p.L912= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- DST | c.4297-2184A>T | Intron (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- NRXN3 | c.989-7440C>T | Intron (SNP) | VAF 44/78 reads (56%) | called by muse, mutect2, varscan2
- TMEM167B | chr1:109100381 G>C | 3'Flank (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- ZNF423 | c.40+33065G>A | Intron (SNP) | VAF 17/28 reads (61%) | catalogued as rs776265059; called by muse, mutect2, varscan2
